Surgical pathology report (de-identified scan), TCGA case TCGA-78-7539, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Prince Charles Hospital, specimen TCGA-78-7539-01A (Primary Tumor).

[page 1 of 2]
SEE SUPPLEMENTARY REPORT BELOW

HISTORY

Right UL bronchial ca.

MACROSCOPIC

Three specimens received

1: The specimen is labelled 'right upper lobe' and consists of a right upper lobectomy measuring 145 x 105 x 45 mm. On the medial surface, inferior the hilum is a staple line measuring 70 mm in length. This is removed (4 mm of tissue) and it, and the bronchial margin is inked blue. There is extensive puckering of the pleura superiorly at the apex over a distance of 40mm. This surface has been inked black. Underneath the puckering is a tan and black nodule with a pushing edge that measures 52 x 51 x 40 mm. The tumour appears to abut the pleural surface in multiple areas. It is 20 mm from the bronchial resection margin. No other lesions are identified within the lung. [1A, bronchial margin; 1B, two hilar lymph nodes; 1C-F, RS of tumour including pleura; 1G, RS of normal lung tissue Note: specimen has been sampled for research]

2: The specimen is labelled 'number 10 lymph node' and consists of four pieces of tan and black tissue, the largest piece measuring 15 x 12 x 10 mm. [BIT, 2A]

3: The specimen is labelled 'number 11 lymph node' and consists of a piece of tan and black tissue measuring 12 x 9 x 6 mm. [3A, lymph node bisected and BIT]

MICROSCOPIC

1: Sections show a moderately differentiated adenocarcinoma with 30% lepidic, 30% acinar, 35% papillary and 5% micropapillary growth. Part of the tumour is composed of elastotic scarring. The lesion is subpleural and focal visceral pleural invasion is identified. Blood vessel and probable lymphatic permeation is seen. No perineural permeation is identified. The lesion is well clear of the bronchial resection margin. No lymph node metastases are seen. Away from the tumour, the lung shows evidence of mild emphysema and a patchy mild inflammation including interstitial chronic inflammation, small numbers of airspace and interstitial non-necrotising granulomata and rare plugs of organising pneumonia. The inflammation is best seen adjacent the tumour but focally involves the distant lung.

2: Sections of the lymph node fragments show reactive changes only. There is no evidence of malignancy. Prominent sinus histiocytosis is noted.

3: Sections of the lymph node show reactive changes only. There is no evidence of malignancy. Prominent sinus histiocytosis is noted.

SUMMARY

Right upper lobe and No. 10 and 11 lymph nodes:

A: Moderately differentiated adenocarcinoma; 52 mm in maximal dimension.

B: Blood vessel and probable lymphatic invasion present; no perineural invasion seen.

C: Visceral pleural invasion identified; clear of bronchial margin.

D: No lymph node metastases.

[page 2 of 2]
E: T2bN0Mx

F: Non-neoplastic lung: Mild emphysema and patchy mild inflammatory changes with some features suggesting extrinsic allergic alveolitis (hypersensitivity pneumonitis).

SUPPLEMENTARY REPORT

1: Special stains confirm the presence of invasion through the elastin layers of the visceral pleura. In this section, tumour is not present on the surface.

T-28000 M-81403 P1-03000

Source: NCI Genomic Data Commons file cf312f7d-f8cf-47e9-921d-1d56636a2c8c (TCGA-78-7539.686BC9A9-71B6-4C27-A76D-4CA9713FBDBE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).